Somatic mutation profile of tumor specimen MBCProject_3020_T2_WES (aliquot MBCProject_3020_T2_WES_1) from CMI case MBCProject_3020, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 34.6 years (12,644 days).
Specimen MBCProject_3020_T2_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f72c6e56-3e2c-41a6-a2be-a247dd5e2be5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3020_SALIVA (Saliva), aliquot MBCProject_3020_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e10ee41-ac2d-4073-95cb-64e0079e838a

The open-access MAF lists 59 somatic variants for this specimen: 33 protein-altering or splice-affecting, 14 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 14, 5'UTR 4, Intron 4, RNA 2, Nonsense Mutation 1, 3'UTR 1, Frame Shift Ins 1, Splice Region 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB6 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as rs778541482, COSV54696489; called by muse, mutect2, varscan2
- APPL1 | c.1853C>T p.S618F | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs372104157; called by muse, mutect2, varscan2
- BTNL8 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs766111997, COSV51456683, COSV51457621, COSV51462136; called by muse, mutect2, varscan2
- CHUK | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1235950507; called by muse, mutect2
- DAO | c.384C>T p.Y128= | Splice Region (SNP) | VAF 86/220 reads (39%) | catalogued as rs747002323, COSV57323611; called by muse, varscan2
- DENND3 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as rs765959967, COSV52800780; called by muse, mutect2, varscan2
- EPSTI1 | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs864622031, COSV58044295; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP10 | c.733G>T p.D245Y | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193557156; called by muse, mutect2, varscan2
- MTMR12 | c.695G>A p.G232D | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99374173; called by muse, mutect2, varscan2
- MTMR8 | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as rs148205697; called by muse, mutect2, varscan2
- PCDHA6 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 89/509 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.013); catalogued as rs782571134, COSV65356666; called by muse, varscan2
- PRR33 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs890846752, COSV61136150; called by muse, mutect2, varscan2
- PTPRQ | c.2470C>T p.P824S (on ENST00000616559; = p.P782S on NM_001145026.2) | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV57054009; called by muse, mutect2, varscan2
- PTPRS | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1397380294, COSV53638223; called by muse, varscan2
- SLFN13 | c.2586G>C p.R862S | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99540340; called by muse, mutect2, varscan2
- SPATA17 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV65126771; called by muse, mutect2
- SPTBN5 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as rs755861492; called by muse, mutect2, varscan2
- TET3 | c.5020G>A p.A1674T | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1464805407; called by muse, mutect2, varscan2
- TGM1 | c.1674G>C p.E558D | Missense Mutation (SNP) | VAF 9/227 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs1373236187, COSV52863478; called by muse, mutect2
- TSEN34 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748455127; called by muse, mutect2, varscan2
- TYMP | c.1436C>A p.P479Q | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1245466741; called by muse, mutect2, varscan2
- CD1A | c.327T>A p.Y109* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | called by muse, varscan2
- CFAP47 | c.6967G>A p.E2323K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FBXL18 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FEM1A | c.1082A>T p.E361V | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- GATA3 | c.1247dup p.T417Dfs*90 | Frame Shift Ins (INS) | VAF 34/114 reads (30%) | called by mutect2, pindel, varscan2
- GK5 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.305); called by muse, mutect2
- MDGA2 | c.3036del p.I1014Lfs*8 (on ENST00000399232 / NM_001113498.2; = p.I716Lfs*8 on NM_182830.4) | Frame Shift Del (DEL) | VAF 28/148 reads (19%) | called by mutect2, pindel, varscan2
- SKOR1 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SYNE2 | c.10459A>C p.N3487H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- TET3 | c.4414C>T p.L1472F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- TMCC2 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USH2A | c.8556G>T p.L2852F | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ARHGAP23 | c.2616C>T p.P872= | Silent (SNP) | VAF 20/338 reads (6%) | catalogued as rs764381799; called by muse, mutect2
- ARHGEF10L | c.907C>T p.L303= | Silent (SNP) | VAF 29/69 reads (42%) | called by muse, mutect2, varscan2
- CTNND1 | c.993G>A p.S331= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs761698967; called by muse, mutect2
- DSCAML1 | c.2667C>T p.I889= (on ENST00000321322; = p.I829= on NM_020693.4) | Silent (SNP) | VAF 100/278 reads (36%) | catalogued as rs141950419, COSV100356709; called by muse, mutect2, varscan2
- FEM1A | c.1083G>A p.E361= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs746506477; called by muse, mutect2, varscan2
- PCDHGA9 | c.1242A>G p.K414= | Silent (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2, varscan2
- PLD6 | c.195C>A p.L65= | Silent (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- PSTPIP1 | c.180C>T p.I60= | Silent (SNP) | VAF 36/69 reads (52%) | catalogued as rs370802825; called by muse, mutect2, varscan2
- RBMXL3 | c.57C>T p.T19= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs782631665, COSV57759227; called by muse, mutect2
- RELN | c.9975T>A p.T3325= | Silent (SNP) | VAF 77/138 reads (56%) | called by muse, mutect2, varscan2
- RYR1 | c.3516A>T p.S1172= | Silent (SNP) | VAF 84/208 reads (40%) | called by muse, mutect2, varscan2
- SEMA4A | c.954C>T p.P318= | Silent (SNP) | VAF 48/291 reads (16%) | called by muse, mutect2, varscan2
- SEMA6D | c.1389C>T p.S463= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as rs148847985; called by muse, mutect2, varscan2
- SYNE3 | c.1308C>T p.A436= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as rs1303666861, COSV62078895; called by muse, mutect2
- ACTG1 | c.-415G>T | 5'UTR (SNP) | VAF 22/107 reads (21%) | called by muse, mutect2, varscan2
- ATP2B2 | c.*57G>A | 3'UTR (SNP) | VAF 62/287 reads (22%) | catalogued as rs373130153; called by muse, mutect2, varscan2
- CSH1 | c.456+106G>T | Intron (SNP) | VAF 65/833 reads (8%) | called by muse, mutect2
- CYB5R1 | c.-5C>G | 5'UTR (SNP) | VAF 20/180 reads (11%) | catalogued as rs1360184360; called by muse, mutect2
- HSF4 | c.1254+14C>T | Intron (SNP) | VAF 42/152 reads (28%) | catalogued as rs751504671; called by muse, mutect2, varscan2
- LASP1 | c.-2C>G | 5'UTR (SNP) | VAF 76/1061 reads (7%) | catalogued as COSV100530472; called by muse, mutect2
- NRG1 | c.502+31354G>A | Intron (SNP) | VAF 42/135 reads (31%) | catalogued as rs1183763274; called by muse, mutect2, varscan2
- OR2W5 | n.537C>A | RNA (SNP) | VAF 40/148 reads (27%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.582+32804C>T | Intron (SNP) | VAF 23/132 reads (17%) | called by muse, mutect2
- PDE6G | c.-10C>T | 5'UTR (SNP) | VAF 24/125 reads (19%) | called by muse, mutect2, varscan2
- PFKFB1 | chrX:54998452 C>A | 5'Flank (SNP) | VAF 36/110 reads (33%) | called by muse, mutect2, varscan2
- SSPOP | n.10498G>A | RNA (SNP) | VAF 25/92 reads (27%) | catalogued as rs770542901, COSV100948379; called by muse, mutect2, varscan2
